Gene-level copy-number profile of tumor specimen TCGA-2Y-A9GZ-01A from TCGA case TCGA-2Y-A9GZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 82.4 years (30,082 days).
Specimen TCGA-2Y-A9GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.43d84f38-74aa-4d87-b87f-7aaab146ee17.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9GZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e3da541-9e93-4118-adee-96e8997fc2d6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 116; copy number 2: 3,341; copy number 3: 26,651; copy number 4: 28,244; copy number 5: 144; copy number 6: 368; copy number 7: 394; copy number 8: 1; copy number 9: 451; copy number 10: 52; copy number 11: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9GZ-01A-11D-A38W-01): tumor purity 0.78, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 949 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:68,087,161–68,198,407, 4 genes, copy number 7: AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219.
- chr5:96,050,115–96,215,519, 1 gene, copy number 8 (within-gene range 4–8): MIR583HG.
- chr6:8,411,435–8,435,561, 1 gene, copy number 10: SLC35B3.
- chr6:12,406,486–12,514,724, 2 genes, copy number 7: RN7SKP293, RPL15P3.
- chr7:95,545,191–95,615,132, 2 genes, copy number 9 (within-gene range 4–9): AC002451.1, PDK4.
- chr17:19,215,615–20,591,180, 79 genes, copy number 7–11 (broad region; genes not listed).
- chr17:57,196,081–83,095,122, 860 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 116. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
